Gene-level copy-number profile of tumor specimen TCGA-09-0366-01A from TCGA case TCGA-09-0366, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.0 years (20,440 days).
Specimen TCGA-09-0366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.00014f01-24a5-4226-9ed6-4b9cabacd074.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-0366-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-09-0366-01A|TCGA-09-0366-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8652c2f0-3019-407a-baf7-3886af525736

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,575; copy number 2: 19,386; copy number 3: 23,660; copy number 4: 12,594; copy number 5: 813; copy number 6: 78; copy number 7: 195; copy number 10: 192; copy number 11: 173; copy number 13: 17; copy number 16: 4; copy number 19: 20; copy number 28: 39; copy number 29: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-0366-01): tumor purity 0.68, ploidy 2.87, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 712 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,445,456, 365 genes, copy number 10–11 (within-gene range 3–11) (broad region; genes not listed).
- chr1:155,033,824–155,602,197, 41 genes, copy number 7: DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1.
- chr11:57,861,948–59,143,015, 58 genes, copy number 19–28: OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT.
- chr11:76,137,315–79,989,630, 77 genes, copy number 16–29 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr19:29,775,504–30,713,538, 17 genes, copy number 13 (within-gene range 5–13): AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr20:35,953,617–40,011,323, 102 genes, copy number 7 (broad region; genes not listed).
- chr20:43,914,852–45,317,824, 48 genes, copy number 7 (within-gene range 3–7): TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL.

Autosomal genes at a single copy (total copy number 1): 2,575. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
